Somatic mutation profile of cancer-model specimen HCM-BROD-0234-C49-85M (2D Modified Conditionally Reprogrammed Cells, passage 10; aliquot HCM-BROD-0234-C49-85M-01D-A80U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0234-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Spindle cell sarcoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 76.5 years (27,950 days).
Specimen HCM-BROD-0234-C49-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1991e758-1af5-449d-958f-edac2bcce016.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0234-C49-10B (Blood Derived Normal), aliquot HCM-BROD-0234-C49-10B-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3b4042a-9f0c-46d5-9ed2-81b9df994bbc

The open-access MAF lists 875 somatic variants for this specimen: 540 protein-altering or splice-affecting, 299 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 489, Silent 299, Nonsense Mutation 23, Intron 23, Splice Region 10, Splice Site 7, Frame Shift Del 7, 5'Flank 6, Frame Shift Ins 3, 3'UTR 3, RNA 2, In Frame Del 1.

Variants (750 of 875; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 316/318 reads (99%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 150/257 reads (58%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as rs1057519948, COSV61821585, COSV61824963; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AAAS | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 266/335 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52932091; called by muse, mutect2, varscan2
- ABCB9 | c.849G>A p.G283= | Splice Region (SNP) | VAF 140/208 reads (67%) | catalogued as rs1190968092; called by muse, mutect2, varscan2
- ABCC3 | c.4072G>A p.G1358S | Missense Mutation (SNP) | VAF 250/396 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs187814086, COSV53323190; called by muse, mutect2, varscan2
- AC119396.1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 94/149 reads (63%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.712); catalogued as rs574718933; called by muse, mutect2, varscan2
- ACOD1 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 72/248 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.599); catalogued as rs763833075; called by muse, mutect2, varscan2
- ACOD1 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs538660196; called by muse, mutect2, varscan2
- ACOT9 | c.923A>G p.N308S | Missense Mutation (SNP) | VAF 190/190 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs748728551; called by muse, mutect2, varscan2
- ACTN3 | c.637-1G>A p.X213_splice | Splice Site (SNP) | VAF 142/288 reads (49%) | catalogued as COSV72207668; called by muse, mutect2, varscan2
- ADAMTS20 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV67126043; called by muse, mutect2, varscan2
- ADAR | c.490A>C p.K164Q | Missense Mutation (SNP) | VAF 232/468 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.265); catalogued as COSV52712412; called by mutect2, varscan2
- ADCY5 | c.1874G>A p.G625E | Missense Mutation (SNP) | VAF 76/320 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59201376; called by muse, mutect2, varscan2
- ADGRF5 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1373208554; called by muse, mutect2, varscan2
- ADGRL2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54655701; called by muse, mutect2, varscan2
- AFF2 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 187/187 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs782804418; called by muse, mutect2, varscan2
- ALOX5 | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 254/525 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs777199179, COSV65553342; called by muse, mutect2, varscan2
- ANKFN1 | c.1215G>A p.R405= | Splice Region (SNP) | VAF 175/256 reads (68%) | catalogued as rs747822420; called by muse, mutect2, varscan2
- ANKRD12 | c.5194C>T p.P1732S | Missense Mutation (SNP) | VAF 157/200 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs1014443518, COSV100040913, COSV50819304; called by muse, mutect2, varscan2
- ANKRD16 | c.657C>A p.D219E | Missense Mutation (SNP) | VAF 160/313 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.299); catalogued as COSV51948652; called by muse, mutect2, varscan2
- APBB1IP | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 150/304 reads (49%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs1029796857; called by muse, varscan2
- ARHGAP21 | c.2774C>T p.S925F | Missense Mutation (SNP) | VAF 199/464 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1265976883; called by muse, mutect2, varscan2
- ARHGEF5 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 156/631 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV99282861, COSV99283215; called by muse, mutect2, varscan2
- ASXL1 | c.2309C>T p.S770L | Missense Mutation (SNP) | VAF 269/410 reads (66%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as COSV60103934, COSV60119071; called by muse, mutect2, varscan2
- ATP1B2 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 248/480 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as rs752825639; called by muse, mutect2
- ATP2A1 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 236/316 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as rs937724681, COSV63921399; called by muse, varscan2
- ATP8B2 | c.2251G>A p.E751K (on ENST00000672630; = p.E718K on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 149/310 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV59246841; called by muse, mutect2, varscan2
- BCORL1 | c.3601G>A p.E1201K | Missense Mutation (SNP) | VAF 196/197 reads (99%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs372174837; called by muse, mutect2, varscan2
- BMP1 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 77/382 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1398538193; called by muse, varscan2
- BRCA1 | c.3943C>T p.P1315S | Missense Mutation (SNP) | VAF 257/549 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.046); catalogued as COSV58803516; called by muse, mutect2, varscan2
- C6orf15 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 18/642 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1454509351; called by muse, mutect2
- C7 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 155/251 reads (62%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV57471726; called by muse, mutect2, varscan2
- CAPN3 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 419/543 reads (77%) | SIFT tolerated (0.22); PolyPhen benign (0.261); catalogued as rs756192789, COSV58820671; called by muse, mutect2, varscan2
- CARD11 | c.2270G>A p.G757E | Missense Mutation (SNP) | VAF 111/369 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs568928567, COSV99052457; called by muse, mutect2, varscan2
- CC2D1B | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 289/290 reads (100%) | catalogued as rs773525251; called by muse, varscan2
- CCDC141 | c.2983G>A p.D995N | Missense Mutation (SNP) | VAF 327/404 reads (81%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs752646500; called by muse, mutect2, varscan2
- CCL1 | c.77T>G p.M26R | Missense Mutation (SNP) | VAF 116/215 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs765973747; called by muse, mutect2, varscan2
- CDH23 | c.8726G>A p.S2909N | Missense Mutation (SNP) | VAF 64/253 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs397517361; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDKN2AIP | c.1347G>T p.W449C | Missense Mutation (SNP) | VAF 64/405 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100187658; called by muse, mutect2, varscan2
- CEACAM7 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 65/108 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV50073185; called by muse, mutect2, varscan2
- CES3 | c.1240G>A p.G414S | Missense Mutation (SNP) | VAF 363/363 reads (100%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.458); catalogued as rs763155745; called by muse, mutect2, varscan2
- CHGB | c.1432G>A p.G478R | Missense Mutation (SNP) | VAF 128/191 reads (67%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs774344332; called by muse, mutect2, varscan2
- CHST9 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV52429078; called by muse, mutect2, varscan2
- CLCN7 | c.1667T>G p.L556R | Missense Mutation (SNP) | VAF 397/502 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99247716; called by muse, mutect2, varscan2
- CNTN5 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 85/174 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as COSV54281336, COSV54342027; called by muse, mutect2, varscan2
- COL11A1 | c.3008G>A p.G1003E | Missense Mutation (SNP) | VAF 258/258 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62173003; called by muse, mutect2, varscan2
- COL9A1 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 139/148 reads (94%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.472); catalogued as COSV57886010; called by muse, mutect2, varscan2
- CPLANE1 | c.8668G>T p.D2890Y | Missense Mutation (SNP) | VAF 114/365 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV57059989, COSV99950331; called by muse, mutect2, varscan2
- CRB2 | c.859G>A p.G287S | Missense Mutation (SNP) | VAF 147/779 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as COSV63503667; called by muse, mutect2, varscan2
- CRB2 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 144/775 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs1442571958, COSV63505898; called by muse, mutect2, varscan2
- CRISPLD1 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 153/308 reads (50%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as rs1321970308; called by muse, mutect2, varscan2
- CROCC | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 290/290 reads (100%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV65015070; called by muse, mutect2, varscan2
- CSMD1 | c.8944C>T p.P2982S (on ENST00000520002; = p.P2981S on NM_033225.6) | Missense Mutation (SNP) | VAF 122/150 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59326145; called by muse, mutect2, varscan2
- CSN2 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 238/238 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs980267132, COSV100778821, COSV61992322; called by muse, mutect2, varscan2
- CTR9 | c.2665C>T p.L889F | Missense Mutation (SNP) | VAF 122/232 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63728426; called by muse, mutect2, varscan2
- CUL7 | c.2492C>T p.S831F | Missense Mutation (SNP) | VAF 291/301 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs369629454; called by muse, mutect2, varscan2
- CUL9 | c.7318G>A p.E2440K | Missense Mutation (SNP) | VAF 208/215 reads (97%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs756475860; called by muse, mutect2, varscan2
- CXXC5 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 98/311 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs762307804, COSV100210835; called by muse, mutect2, varscan2
- CYP11A1 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 74/457 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs999606408; called by muse, mutect2, varscan2
- CYP2A6 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 68/286 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.105); catalogued as COSV104397077; called by muse, mutect2, varscan2
- CYP2C8 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 167/249 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs772497816; called by muse, mutect2, varscan2
- CYP2C9 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 289/289 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV53246817; called by muse, mutect2, varscan2
- DACT1 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 66/423 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.368); catalogued as rs780349654; called by muse, mutect2, varscan2
- DAOA | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV61601631; called by muse, mutect2, varscan2
- DCC | c.4186C>T p.P1396S | Missense Mutation (SNP) | VAF 59/343 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV71431528; called by muse, mutect2, varscan2
- DEUP1 | c.1648G>A p.D550N | Missense Mutation (SNP) | VAF 70/160 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as COSV99977049, COSV99977511; called by muse, mutect2, varscan2
- DHX30 | c.2863C>T p.R955C (on ENST00000445061 / NM_138615.3; = p.R916C on NM_014966.3) | Missense Mutation (SNP) | VAF 202/487 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as rs766335935; called by muse, mutect2, varscan2
- DIAPH2 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 116/116 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100235878; called by muse, mutect2, varscan2
- DIAPH3 | c.3499G>A p.E1167K | Missense Mutation (SNP) | VAF 161/247 reads (65%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as rs775688879; called by muse, mutect2, varscan2
- DNAH6 | c.6629C>T p.S2210L | Missense Mutation (SNP) | VAF 143/387 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs1365729676, COSV52851796; called by muse, mutect2, varscan2
- DOCK1 | c.4455G>A p.V1485= | Splice Region (SNP) | VAF 127/190 reads (67%) | catalogued as rs370127033; called by muse, mutect2, varscan2
- DRD5 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 367/432 reads (85%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as rs773943990, COSV58578778; called by muse, mutect2, varscan2
- DSG1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57133137; called by muse, mutect2, varscan2
- DUSP8 | c.421C>G p.P141A | Missense Mutation (SNP) | VAF 124/420 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV100524517; called by muse, mutect2, varscan2
- DYRK3 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 160/524 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs202021957; called by muse, mutect2
- ERICH3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 192/193 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs267598719; called by muse, mutect2, varscan2
- ERICH3 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs868787285, COSV58602614; called by muse, mutect2, varscan2
- FIGNL1 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 235/374 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780152080; called by muse, mutect2, varscan2
- FILIP1 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV52726507; called by muse, mutect2
- FIS1 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 243/428 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99778907; called by muse, mutect2, varscan2
- FLRT3 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 66/218 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777359374, COSV54039664; called by muse, mutect2, varscan2
- FRMD7 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 230/230 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs750688292; called by muse, mutect2, varscan2
- GABBR1 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 14/432 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63541692; called by muse, mutect2
- GABRB1 | c.367T>A p.F123I | Missense Mutation (SNP) | VAF 112/317 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99783881; called by muse, varscan2
- GADL1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 158/290 reads (54%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.537); catalogued as rs1409667154, COSV56985756; called by muse, mutect2, varscan2
- GLT1D1 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs781124799, COSV55882678; called by muse, mutect2, varscan2
- GLT1D1 | c.931G>A p.E311K (on ENST00000442111 / NM_001366889.1; = p.E231K on NM_144669.3) | Missense Mutation (SNP) | VAF 242/307 reads (79%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55882961; called by muse, mutect2, varscan2
- GOLGA3 | c.2057G>A p.R686K | Missense Mutation (SNP) | VAF 407/407 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52645192; called by muse, mutect2, varscan2
- GOLGA6B | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs1304327858; called by mutect2, varscan2
- GPX2 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 87/509 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs200618749; called by muse, mutect2, varscan2
- GRK7 | c.115C>A p.L39M | Missense Mutation (SNP) | VAF 334/472 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747391734, COSV99379754, COSV99380173; called by muse, mutect2, varscan2
- GRN | c.1489A>G p.K497E | Missense Mutation (SNP) | VAF 288/617 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs952213951; called by muse, mutect2, varscan2
- H1-7 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 131/585 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV58601915; called by muse, mutect2, varscan2
- H1-8 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 289/381 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs752419831; called by muse, mutect2, varscan2
- HEATR1 | c.2789C>T p.P930L | Missense Mutation (SNP) | VAF 172/342 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as rs1294243318; called by muse, mutect2, varscan2
- HEATR5B | c.4691C>T p.S1564F | Missense Mutation (SNP) | VAF 288/483 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as rs893846419; called by muse, mutect2, varscan2
- HEPACAM2 | c.467C>T p.P156L (on ENST00000394468 / NM_001039372.4; = p.P144L on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 175/295 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs865778058; called by muse, mutect2, varscan2
- HNMT | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 215/301 reads (71%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.976); catalogued as COSV54511022; called by muse, mutect2, varscan2
- HS3ST4 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV58806132; called by muse, mutect2, varscan2
- HSCB | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 360/683 reads (53%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs932257117; called by muse, mutect2, varscan2
- HSPA12A | c.1351C>A p.L451I | Missense Mutation (SNP) | VAF 78/310 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV65021712; called by muse, mutect2, varscan2
- HTR2A | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 139/205 reads (68%) | SIFT tolerated (0.19); PolyPhen benign (0.444); catalogued as COSV66326570; called by muse, mutect2, varscan2
- HTR4 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867725219, COSV58789896; called by muse, mutect2, varscan2
- IFT88 | c.433G>A p.E145K (on ENST00000319980 / NM_001318493.2; = p.E136K on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as rs764712905, COSV60673703; called by muse, mutect2, varscan2
- IGF2BP3 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 181/298 reads (61%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.846); catalogued as rs764971109, COSV51679803; called by muse, mutect2, varscan2
- IGHV1-18 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 319/807 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as rs373213848; called by muse, varscan2
- INTU | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 287/375 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1176904927; called by muse, mutect2, varscan2
- IRF2BP2 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 382/734 reads (52%) | catalogued as COSV100784403; called by muse, mutect2, varscan2
- ITPR1 | c.7963G>A p.E2655K (on ENST00000354582; = p.E2600K on NM_002222.7) | Missense Mutation (SNP) | VAF 237/364 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV56978849; called by muse, mutect2, varscan2
- JUND | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 276/424 reads (65%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.791); catalogued as rs980876053; called by muse, mutect2, varscan2
- KCNH8 | c.3227G>A p.G1076E | Missense Mutation (SNP) | VAF 263/426 reads (62%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.027); catalogued as rs866087313, COSV60473823; called by muse, mutect2, varscan2
- KCNJ3 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 185/281 reads (66%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.038); catalogued as COSV54534242; called by muse, mutect2, varscan2
- KCNT1 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 181/670 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as rs778405770, COSV53681862; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCTD5 | c.675G>A p.K225= | Splice Region (SNP) | VAF 238/290 reads (82%) | catalogued as rs1250492026; called by muse, mutect2, varscan2
- KDM4C | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 111/111 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs750594288; called by muse, mutect2, varscan2
- KDM4F | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 123/248 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs782056487; called by muse, mutect2, varscan2
- KIF21A | c.2305del p.T769Qfs*5 (on ENST00000361418 / NM_001378440.1; = p.T756Qfs*5 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/174 reads (20%) | catalogued as rs1219032396; called by mutect2, pindel, varscan2
- KIF26B | c.5957C>T p.P1986L | Missense Mutation (SNP) | VAF 341/635 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV63650950; called by muse, mutect2, varscan2
- KLHL4 | c.2152C>T p.P718S | Missense Mutation (SNP) | VAF 99/99 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV64144326; called by muse, mutect2, varscan2
- KMT5B | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 164/349 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV58564431; called by muse, mutect2, varscan2
- KRTAP19-3 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 122/579 reads (21%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.013); catalogued as rs770911384, COSV100477476, COSV61855299; called by muse, mutect2, varscan2
- KRTAP24-1 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 206/259 reads (80%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); catalogued as rs774083954, COSV61088971; called by muse, mutect2, varscan2
- LDLR | c.2549G>A p.R850K | Missense Mutation (SNP) | VAF 162/256 reads (63%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.676); catalogued as rs879255228, CM067688; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRFN5 | c.1328G>A p.G443E | Missense Mutation (SNP) | VAF 90/140 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs760158675; called by muse, mutect2, varscan2
- LRRIQ4 | c.1375C>A p.L459I | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as rs1002946974; called by muse, mutect2, varscan2
- MCCC1 | c.1394C>T p.T465I | Missense Mutation (SNP) | VAF 118/169 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1000891879; called by muse, mutect2, varscan2
- ME3 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 223/437 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as rs770032541; called by muse, mutect2, varscan2
- MED16 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 139/240 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs969601088; called by muse, mutect2, varscan2
- MERTK | c.944G>A p.R315K | Missense Mutation (SNP) | VAF 172/236 reads (73%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs886871857; called by muse, mutect2, varscan2
- MMP14 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 81/279 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1456467056; called by muse, mutect2, varscan2
- MMP16 | c.1530C>G p.F510L | Missense Mutation (SNP) | VAF 165/227 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54194898; called by muse, mutect2, varscan2
- MMS22L | c.1787C>T p.S596L | Missense Mutation (SNP) | VAF 171/183 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as rs866715074, COSV51517224; called by muse, mutect2, varscan2
- MPPED2 | c.600G>A p.W200* | Nonsense Mutation (SNP) | VAF 732/837 reads (87%) | catalogued as COSV63901781; called by muse, mutect2, varscan2
- MROH2B | c.2800C>A p.L934I | Missense Mutation (SNP) | VAF 57/375 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs1448281063; called by muse, mutect2, varscan2
- MTHFD2 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 182/501 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1481756808; called by muse, mutect2, varscan2
- MUC12 | c.12187G>A p.E4063K (on ENST00000379442; = p.E3920K on NM_001164462.1) | Missense Mutation (SNP) | VAF 127/1227 reads (10%) | SIFT tolerated (0.12); catalogued as rs750395168; called by muse, mutect2, varscan2
- MUC16 | c.6578C>T p.S2193F | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV67462513; called by muse, mutect2, varscan2
- MUC22 | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 624/655 reads (95%) | SIFT tolerated (0.36); catalogued as rs567001093; called by muse, mutect2, varscan2
- MYH4 | c.4197G>C p.Q1399H | Missense Mutation (SNP) | VAF 51/333 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.852); catalogued as rs147966650; called by muse, mutect2, varscan2
- MYLK2 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 185/631 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV101044917; called by muse, mutect2, varscan2
- MYO16 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.198); catalogued as rs201258873; called by muse, mutect2, varscan2
- MYT1L | c.2276G>A p.R759Q | Missense Mutation (SNP) | VAF 303/508 reads (60%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1384454881, COSV67719715; called by muse, mutect2, varscan2
- NAA60 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 316/410 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1567396028, COSV62655823; called by muse, mutect2, varscan2
- NBEA | c.8480G>A p.R2827H | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as rs376983676; called by muse, mutect2, varscan2
- NCOR2 | c.3200C>T p.P1067L | Missense Mutation (SNP) | VAF 480/619 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775451734; called by muse, mutect2, varscan2
- NEO1 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 87/461 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV56069672; called by muse, mutect2, varscan2
- NES | c.2497G>A p.G833R | Missense Mutation (SNP) | VAF 266/574 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV63961181; called by muse, varscan2
- NOTCH2 | c.6058G>A p.E2020K | Missense Mutation (SNP) | VAF 220/221 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56702339; called by muse, mutect2, varscan2
- NOTUM | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 412/713 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1567937076; called by muse, mutect2, varscan2
- NPAS1 | c.1603G>A p.G535S | Missense Mutation (SNP) | VAF 381/562 reads (68%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs1358209916; called by muse, mutect2, varscan2
- NRXN1 | c.4391C>T p.S1464F | Missense Mutation (SNP) | VAF 206/394 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV60513495, COSV60515579; called by muse, mutect2, varscan2
- NRXN3 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 371/468 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs765822699; called by muse, mutect2, varscan2
- NRXN3 | c.371G>A p.G124D (on ENST00000557594 / NM_001272020.2; = p.G756D on NM_004796.6) | Missense Mutation (SNP) | VAF 67/429 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs143930897; called by muse, mutect2, varscan2
- OBSCN | c.17758C>T p.R5920C | Missense Mutation (SNP) | VAF 347/740 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372074892; called by muse, mutect2, varscan2
- ODAM | c.142-1G>A p.X48_splice | Splice Site (SNP) | VAF 117/117 reads (100%) | catalogued as rs772957913; called by muse, mutect2, varscan2
- OGDHL | c.2516C>T p.P839L | Missense Mutation (SNP) | VAF 150/342 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200530979, COSV65104219; called by muse, mutect2, varscan2
- OPRM1 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 278/298 reads (93%) | SIFT tolerated (0.5); PolyPhen benign (0.386); catalogued as rs187512719, COSV57674395; called by muse, mutect2, varscan2
- OPTN | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 260/534 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs888024328; called by muse, mutect2, varscan2
- OR14I1 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 123/268 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61199667; called by muse, mutect2, varscan2
- OR4D6 | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 148/298 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55658945; called by muse, mutect2, varscan2
- OR4E2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 192/303 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201192739, COSV57731367; called by muse, mutect2
- OR5M1 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV73202117; called by muse, mutect2, varscan2
- OR6C68 | c.487C>T p.H163Y | Missense Mutation (SNP) | VAF 71/318 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV101110020, COSV65564269; called by muse, mutect2, varscan2
- OR6K6 | c.989G>A p.R330K (on ENST00000368144; = p.R306K on NM_001005184.1) | Missense Mutation (SNP) | VAF 113/269 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100933799; called by muse, mutect2, varscan2
- OR8J2 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 72/150 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs1265174005; called by muse, varscan2
- OTOL1 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 189/253 reads (75%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100020227; called by muse, mutect2, varscan2
- PATE1 | c.77G>A p.R26K | Missense Mutation (SNP) | VAF 113/229 reads (49%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV59824348; called by muse, mutect2, varscan2
- PCDHA2 | c.1063C>G p.L355V | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.414); catalogued as rs782551806; called by muse, mutect2, varscan2
- PCDHA3 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 64/245 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782301588; called by muse, mutect2, varscan2
- PCDHB8 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 64/536 reads (12%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.009); catalogued as COSV99177314; called by muse, mutect2, varscan2
- PCDHGA3 | c.197T>A p.I66N | Missense Mutation (SNP) | VAF 108/321 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs772912037; called by muse, mutect2, varscan2
- PCLO | c.13796C>T p.S4599F | Missense Mutation (SNP) | VAF 161/252 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV61616647; called by muse, mutect2, varscan2
- PFAS | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 89/702 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs758915573; called by muse, mutect2, varscan2
- PHLPP2 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 145/145 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as rs762882143, COSV62423892; called by muse, mutect2, varscan2
- PHOSPHO1 | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 392/706 reads (56%) | SIFT tolerated (0.52); PolyPhen benign (0.253); catalogued as rs1365965538; called by muse, varscan2
- PIK3AP1 | c.2027C>G p.T676R | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59531748; called by muse, mutect2, varscan2
- PNMA1 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 380/458 reads (83%) | SIFT tolerated (0.58); PolyPhen benign (0.212); catalogued as COSV99678959; called by muse, mutect2, varscan2
- POTEG | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 356/1170 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs145666754, COSV101611982; called by muse, mutect2
- PPP1R3A | c.2451G>A p.M817I | Missense Mutation (SNP) | VAF 185/341 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52876950; called by muse, mutect2, varscan2
- PRIM1 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 323/381 reads (85%) | SIFT tolerated (0.32); PolyPhen benign (0.042); catalogued as rs201428535, COSV57717575; called by muse, mutect2, varscan2
- PRKDC | c.11590C>T p.R3864C | Missense Mutation (SNP) | VAF 170/230 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs377101643; called by muse, varscan2
- PRKDC | c.9860G>A p.R3287Q | Missense Mutation (SNP) | VAF 229/330 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs765440019, COSV100038414; called by muse, mutect2, varscan2
- PROM2 | c.1888G>T p.V630L | Missense Mutation (SNP) | VAF 386/669 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as rs763434626; called by muse, mutect2, varscan2
- PRR32 | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 206/207 reads (100%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV64420493; called by muse, mutect2, varscan2
- PRR36 | c.2959C>T p.P987S | Missense Mutation (SNP) | VAF 88/282 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs1173420222; called by muse, mutect2, varscan2
- PRRC2A | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 309/319 reads (97%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as rs950589865; called by muse, mutect2, varscan2
- PRRC2C | c.6890C>T p.S2297L (on ENST00000367742; = p.S2295L on NM_015172.4) | Missense Mutation (SNP) | VAF 186/440 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV58902730; called by muse, mutect2, varscan2
- PTPRG | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 232/628 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs149537126; called by muse, mutect2, varscan2
- PTPRJ | c.3241C>T p.R1081C | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1024704269; called by muse, mutect2, varscan2
- R3HDM2 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 75/644 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as rs1467969609; called by muse, mutect2, varscan2
- RASGRP3 | c.810C>T p.N270= | Splice Region (SNP) | VAF 118/239 reads (49%) | catalogued as rs768449180; called by muse, mutect2, varscan2
- RAX | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 498/633 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs778308289; called by muse, mutect2, varscan2
- RBM19 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 265/350 reads (76%) | SIFT tolerated (0.07); PolyPhen benign (0.3); catalogued as COSV55690449; called by muse, mutect2, varscan2
- RCC1L | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 425/688 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); catalogued as rs781836499; called by muse, mutect2, varscan2
- REG3A | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 163/299 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs779093650, COSV100532523, COSV59409425; called by muse, mutect2, varscan2
- RESP18 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.475); catalogued as rs1277356000, COSV61113781; called by muse, mutect2, varscan2
- RGPD8 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 12/148 reads (8%) | catalogued as COSV100221737, COSV56902423; called by muse, mutect2
- RIMS1 | c.3338G>A p.R1113K | Missense Mutation (SNP) | VAF 134/159 reads (84%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.933); catalogued as COSV53475353; called by muse, mutect2, varscan2
- RNF175 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 153/271 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs763159569; called by muse, mutect2, varscan2
- RP1 | c.2435C>T p.P812L | Missense Mutation (SNP) | VAF 177/177 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101587691; called by muse, mutect2, varscan2
- RTL1 | c.1759C>T p.L587F | Missense Mutation (SNP) | VAF 192/670 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV66017477; called by muse, mutect2, varscan2
- SART1 | c.22C>G p.R8G | Missense Mutation (SNP) | VAF 147/328 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as COSV56711700, COSV56712123; called by muse, mutect2, varscan2
- SEMA3E | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 102/297 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV57080425; called by muse, varscan2
- SFTPA2 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 53/297 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs767317715, COSV64882540; called by muse, mutect2, varscan2
- SGSM1 | c.2485G>A p.E829K (on ENST00000400359 / NM_001039948.4; = p.E768K on NM_133454.3) | Missense Mutation (SNP) | VAF 295/575 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV63082814; called by muse, mutect2, varscan2
- SLC23A3 | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 111/250 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.365); catalogued as rs1238008734; called by muse, mutect2, varscan2
- SLC28A1 | c.462-1G>A p.X154_splice | Splice Site (SNP) | VAF 317/400 reads (79%) | catalogued as rs779453805, COSV99723269; called by muse, mutect2, varscan2
- SLC44A3 | c.979C>T p.P327S (on ENST00000271227 / NM_001114106.3; = p.P279S on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 413/414 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as rs756785788, COSV54732162; called by muse, mutect2, varscan2
- SLC44A5 | c.1470G>A p.M490I | Missense Mutation (SNP) | VAF 294/294 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs138689403, COSV63758541; called by muse, mutect2, varscan2
- SLC6A3 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 312/484 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54361959; called by muse, varscan2
- SLC9A4 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 216/321 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370821670; called by muse, mutect2, varscan2
- SPAST | c.684A>T p.E228D | Missense Mutation (SNP) | VAF 120/306 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.225); catalogued as rs1458104027; called by muse, mutect2, varscan2
- SPATA2 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 216/787 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); catalogued as rs752675900; called by muse, mutect2, varscan2
- SPEG | c.9529C>T p.R3177C | Missense Mutation (SNP) | VAF 96/225 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs756642514, COSV100405005; called by muse, mutect2, varscan2
- SPOCK3 | c.940+4A>T | Splice Region (SNP) | VAF 98/157 reads (62%) | catalogued as COSV62732285; called by muse, mutect2, varscan2
- SPTA1 | c.5677G>A p.E1893K | Missense Mutation (SNP) | VAF 97/224 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.062); catalogued as COSV63750730; called by muse, mutect2, varscan2
- SSTR1 | c.1079G>A p.S360N | Missense Mutation (SNP) | VAF 87/270 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV57456379; called by muse, varscan2
- SUCO | c.3391G>A p.A1131T | Missense Mutation (SNP) | VAF 177/409 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV55269679; called by muse, mutect2, varscan2
- SYCE1 | c.550G>A p.E184K (on ENST00000343131 / NM_001143764.3; = p.E148K on NM_130784.3) | Missense Mutation (SNP) | VAF 87/357 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58217684; called by muse, mutect2, varscan2
- SYN3 | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 172/369 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs762240021; called by muse, mutect2, varscan2
- TARS2 | c.1519C>T p.L507F | Missense Mutation (SNP) | VAF 217/419 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.819); catalogued as COSV64695430; called by muse, mutect2, varscan2
- TCERG1 | c.1413_1417del p.E471Dfs*2 | Frame Shift Del (DEL) | VAF 64/102 reads (63%) | catalogued as rs781141103; called by pindel, varscan2
- TECPR1 | c.3086C>T p.P1029L | Missense Mutation (SNP) | VAF 218/364 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1172736194; called by muse, varscan2
- TEX43 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 77/119 reads (65%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as rs770263487, COSV64035944; called by muse, mutect2, varscan2
- TGM6 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 88/248 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs758286096, COSV52479822; called by muse, mutect2, varscan2
- TINAGL1 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 382/383 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54699454; called by muse, mutect2, varscan2
- TLR4 | c.2140C>T p.P714S (on ENST00000355622 / NM_138554.5; = p.P674S on NM_003266.4) | Missense Mutation (SNP) | VAF 438/439 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV62922486; called by muse, mutect2, varscan2
- TMEM132A | c.2789G>A p.G930E (on ENST00000453848 / NM_178031.3; = p.G931E on NM_017870.4) | Missense Mutation (SNP) | VAF 265/565 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.892); catalogued as rs1226949801; called by muse, mutect2, varscan2
- TMEM179 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 178/719 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.052); catalogued as rs1343248254, COSV58795240, COSV58795396; called by muse, mutect2, varscan2
- TMEM236 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 220/495 reads (44%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1376489987; called by muse, mutect2, varscan2
- TNFRSF10B | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 192/254 reads (76%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs770017158; called by muse, mutect2, varscan2
- TNFRSF19 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 163/253 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as rs1408894457; called by muse, mutect2, varscan2
- TNN | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 254/555 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs755253081; called by muse, mutect2, varscan2
- TRPM4 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 196/304 reads (64%) | catalogued as rs750176955, COSV99420688; called by muse, mutect2, varscan2
- TSKS | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 108/285 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs773071788; called by muse, mutect2, varscan2
- TTN | c.24523G>A p.D8175N (on ENST00000591111; = p.D7248N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/527 reads (14%) | PolyPhen probably damaging (0.916); catalogued as rs770655555, COSV59902114; called by muse, mutect2, varscan2
- TTN | c.4678G>A p.E1560K (on ENST00000591111; = p.E1514K on NM_003319.4) | Missense Mutation (SNP) | VAF 371/427 reads (87%) | PolyPhen probably damaging (0.994); catalogued as COSV100594895; called by muse, mutect2, varscan2
- UBR4 | c.12419C>T p.A4140V | Missense Mutation (SNP) | VAF 231/231 reads (100%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.935); catalogued as rs1341280754; called by muse, mutect2, varscan2
- UBR4 | c.3130C>T p.R1044W | Missense Mutation (SNP) | VAF 216/216 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs766351812; called by muse, mutect2, varscan2
- UCP3 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 252/485 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as rs146858543; called by muse, mutect2, varscan2
- UNC5D | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 134/191 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs1189500802, COSV54819138; called by muse, mutect2, varscan2
- USP6NL | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 156/297 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs984195074; called by muse, mutect2, varscan2
- VGLL2 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 39/419 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs1264165017; called by muse, mutect2
- WDR24 | c.1144G>A p.A382T (on ENST00000248142; = p.A252T on NM_032259.4) | Missense Mutation (SNP) | VAF 95/469 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as rs145838196; called by muse, mutect2, varscan2
- WDR87 | c.3875C>T p.P1292L | Missense Mutation (SNP) | VAF 270/356 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58208209; called by muse, mutect2, varscan2
- WDR87 | c.2998C>T p.R1000W | Missense Mutation (SNP) | VAF 183/240 reads (76%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as rs376822850; called by muse, mutect2, varscan2
- ZACN | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 104/412 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as rs898873151, COSV100135861; called by muse, mutect2, varscan2
- ZFHX2 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 81/321 reads (25%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs930794357; called by muse, mutect2, varscan2
- ZNF229 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 100/162 reads (62%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV52164960; called by muse, varscan2
- ZNF256 | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 94/307 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV56596959; called by muse, mutect2, varscan2
- ZNF430 | c.824C>T p.T275I | Missense Mutation (SNP) | VAF 166/206 reads (81%) | SIFT tolerated (0.4); PolyPhen benign (0.082); catalogued as rs745938446; called by muse, mutect2, varscan2
- ZNF468 | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 55/169 reads (33%) | catalogued as rs138449706; called by muse, mutect2, varscan2
- ZNF611 | c.1652C>T p.S551F | Missense Mutation (SNP) | VAF 150/230 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs750313321, COSV60541758; called by muse, mutect2, varscan2
- ZNF628 | c.2831G>A p.G944D | Missense Mutation (SNP) | VAF 258/411 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1173196992; called by muse, mutect2, varscan2
- ZNF710 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 121/733 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.027); catalogued as rs757423885, COSV51565867; called by muse, mutect2, varscan2
- ZNF804B | c.2185C>T p.H729Y | Missense Mutation (SNP) | VAF 152/253 reads (60%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV60832697; called by muse, mutect2, varscan2
- AATK | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 268/711 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- ABCA3 | c.4635G>A p.M1545I | Missense Mutation (SNP) | VAF 431/546 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ABCB9 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 128/186 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, varscan2
- ACACB | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 344/430 reads (80%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACAD9 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 56/284 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ADAM12 | c.2561C>T p.P854L | Missense Mutation (SNP) | VAF 174/255 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAM2 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADAMTSL3 | c.3202G>A p.G1068R | Missense Mutation (SNP) | VAF 386/453 reads (85%) | SIFT tolerated (0.4); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADGRG4 | c.4078C>T p.L1360F | Missense Mutation (SNP) | VAF 196/196 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- AEBP2 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 196/196 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- AFF3 | c.157T>G p.F53V | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKT2 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALKBH1 | c.635del p.F212Sfs*8 | Frame Shift Del (DEL) | VAF 62/529 reads (12%) | called by pindel, varscan2
- ANKRD31 | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AP5B1 | c.1508A>T p.H503L | Missense Mutation (SNP) | VAF 194/417 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- AP5Z1 | c.2008T>C p.F670L | Missense Mutation (SNP) | VAF 224/676 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- ARHGAP5 | c.2084C>T p.P695L | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- AS3MT | c.914A>T p.E305V | Missense Mutation (SNP) | VAF 174/237 reads (73%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- ASB1 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ASIC3 | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 162/438 reads (37%) | called by muse, mutect2, varscan2
- ATMIN | c.1973C>T p.T658I | Missense Mutation (SNP) | VAF 261/261 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ATP13A5 | c.703G>T p.V235F | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- BAG2 | c.223+2_223+3del p.X75_splice | Splice Site (DEL) | VAF 32/221 reads (14%) | called by mutect2, pindel, varscan2
- BARHL2 | c.860G>A p.W287* | Nonsense Mutation (SNP) | VAF 232/233 reads (100%) | called by muse, mutect2, varscan2
- BCAN | c.862G>A p.G288S | Missense Mutation (SNP) | VAF 304/687 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- BCL2L14 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 158/158 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- BCL9 | c.3649G>A p.D1217N | Missense Mutation (SNP) | VAF 188/421 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- BTNL9 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- C15orf40 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 230/294 reads (78%) | SIFT tolerated (0.17); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- C17orf98 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 150/396 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, varscan2
- C6orf15 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 18/636 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.468); called by muse, mutect2
- CACNA1E | c.5028G>T p.K1676N | Missense Mutation (SNP) | VAF 96/542 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, varscan2
- CASZ1 | c.2653C>G p.L885V | Missense Mutation (SNP) | VAF 59/265 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CCDC168 | c.17860G>A p.E5954K | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- CCDC168 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CCDC61 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 290/438 reads (66%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CCDC88A | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 135/352 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CCN2 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 126/140 reads (90%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CCR2 | c.800C>T p.T267I | Missense Mutation (SNP) | VAF 98/343 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CCZ1 | c.1098G>T p.R366S | Missense Mutation (SNP) | VAF 111/132 reads (84%) | SIFT tolerated (0.27); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CD36 | c.757T>C p.S253P | Missense Mutation (SNP) | VAF 146/253 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CDC42BPG | c.2968C>T p.P990S | Missense Mutation (SNP) | VAF 206/431 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- CDH19 | c.836T>A p.M279K | Missense Mutation (SNP) | VAF 62/307 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CDH19 | c.835A>T p.M279L | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH26 | c.1283G>C p.R428T | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- CEACAM6 | c.76A>G p.T26A | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CHD8 | c.1559A>C p.K520T (on ENST00000646647 / NM_001170629.2; = p.K241T on NM_020920.4) | Missense Mutation (SNP) | VAF 196/284 reads (69%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHIC2 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 110/147 reads (75%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- CKMT2 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLDN8 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 217/282 reads (77%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLIP2 | c.1320-3_1329del p.X440_splice | Splice Site (DEL) | VAF 104/224 reads (46%) | called by pindel, varscan2
- CNTROB | c.2053C>T p.P685S | Missense Mutation (SNP) | VAF 349/618 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- COL15A1 | c.3364C>T p.P1122S | Missense Mutation (SNP) | VAF 532/533 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL16A1 | c.2231C>T p.P744L | Missense Mutation (SNP) | VAF 573/573 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL4A3 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A3 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL8A1 | c.1615G>A p.G539R | Missense Mutation (SNP) | VAF 108/381 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL8A1 | c.1616G>A p.G539E | Missense Mutation (SNP) | VAF 107/378 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL9A2 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 504/504 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COLEC12 | c.2070G>A p.W690* | Nonsense Mutation (SNP) | VAF 51/278 reads (18%) | called by muse, mutect2, varscan2
- CPNE3 | c.1114T>A p.C372S | Missense Mutation (SNP) | VAF 130/302 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- CRELD2 | c.766T>A p.C256S | Missense Mutation (SNP) | VAF 274/553 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- CROCC2 | c.4058C>A p.P1353H | Missense Mutation (SNP) | VAF 116/302 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- CUL9 | c.1594A>T p.K532* | Nonsense Mutation (SNP) | VAF 81/287 reads (28%) | called by muse, mutect2, varscan2
- CYC1 | c.480A>T p.E160D | Missense Mutation (SNP) | VAF 203/271 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP2A6 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 66/285 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- DGKD | c.2412_2414del p.G805del (on ENST00000264057 / NM_152879.3; = p.G761del on NM_003648.3 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 43/132 reads (33%) | called by mutect2, pindel*, varscan2*
- DGKI | c.1192A>C p.M398L | Missense Mutation (SNP) | VAF 87/380 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- DHX30 | c.292G>A p.E98K (on ENST00000445061 / NM_138615.3; = p.E59K on NM_014966.3) | Missense Mutation (SNP) | VAF 132/370 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- DIAPH1 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 119/186 reads (64%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.017); called by muse, varscan2
- DIAPH3 | c.276C>A p.N92K | Missense Mutation (SNP) | VAF 145/222 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- DIDO1 | c.5506G>A p.G1836R | Missense Mutation (SNP) | VAF 178/621 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- DNAH10 | c.6274G>A p.V2092M (on ENST00000409039; = p.V2031M on NM_207437.3) | Missense Mutation (SNP) | VAF 75/371 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DNAJC18 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 123/201 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK1 | c.4456G>A p.E1486K | Missense Mutation (SNP) | VAF 129/192 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- DOCK1 | c.5533C>T p.P1845S | Missense Mutation (SNP) | VAF 234/303 reads (77%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DST | c.5054C>T p.A1685V | Missense Mutation (SNP) | VAF 239/304 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- DUSP22 | c.435+7A>T | Splice Region (SNP) | VAF 60/1028 reads (6%) | called by muse, mutect2
- DZIP3 | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- EBI3 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 172/272 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- EFCAB13 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 134/223 reads (60%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- EFHC1 | c.1281A>G p.E427= | Splice Region (SNP) | VAF 35/302 reads (12%) | called by muse, mutect2, varscan2
- EHD4 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 467/565 reads (83%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- EHMT2 | c.1772C>T p.P591L | Missense Mutation (SNP) | VAF 27/664 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2
- EIF3A | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ELOVL3 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 78/356 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- EPX | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 124/490 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- ERC2 | c.791_792insC p.R264Sfs*8 | Frame Shift Ins (INS) | VAF 106/417 reads (25%) | called by mutect2, pindel, varscan2
- ERFL | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 248/399 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- EXOC3 | c.731G>A p.W244* | Nonsense Mutation (SNP) | VAF 157/504 reads (31%) | called by muse, mutect2, varscan2
- FAM133A | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 182/182 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- FAM155A | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 206/290 reads (71%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT1 | c.5634_5635dup p.F1879Cfs*19 | Frame Shift Ins (INS) | VAF 280/676 reads (41%) | called by mutect2, pindel, varscan2
- FAT3 | c.2348T>C p.L783P | Missense Mutation (SNP) | VAF 112/247 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- FBXO30 | c.206T>C p.F69S | Missense Mutation (SNP) | VAF 203/219 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- FDPS | c.383T>C p.L128S | Missense Mutation (SNP) | VAF 147/384 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- FGD5 | c.1574C>T p.S525L | Missense Mutation (SNP) | VAF 163/393 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FN1 | c.5924C>T p.A1975V | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- FOXD4L5 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 428/968 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); called by muse, varscan2
- FREM3 | c.4374T>A p.D1458E | Missense Mutation (SNP) | VAF 222/352 reads (63%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- GALR3 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 345/670 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GART | c.2080C>G p.L694V | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- GATA6 | c.1456G>C p.E486Q | Missense Mutation (SNP) | VAF 191/255 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- GLDC | c.1667G>A p.G556E | Missense Mutation (SNP) | VAF 166/166 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GLI2 | c.2998G>A p.G1000S (on ENST00000361492 / NM_001374353.1; = p.G1017S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 162/596 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- GSDME | c.221_222del p.E74Vfs*79 | Frame Shift Del (DEL) | VAF 80/325 reads (25%) | called by mutect2, pindel, varscan2
- GTF2F1 | c.1436C>T p.T479I | Missense Mutation (SNP) | VAF 195/281 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GTPBP1 | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 285/603 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- GZF1 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 151/223 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- HHIP | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 130/232 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, varscan2
- HYDIN | c.14182C>T p.P4728S | Missense Mutation (SNP) | VAF 132/196 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IFNA10 | c.318A>T p.E106D | Missense Mutation (SNP) | VAF 198/261 reads (76%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFNL2 | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 93/282 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGBP1P2 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 162/516 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.331); called by muse, mutect2
- IGLC7 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 288/600 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- IGSF10 | c.1688C>T p.T563I | Missense Mutation (SNP) | VAF 207/304 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- IL7R | c.502G>C p.A168P | Missense Mutation (SNP) | VAF 113/306 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- INHBE | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 95/1074 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.069); called by muse, mutect2
- INPP5B | c.2266A>G p.K756E (on ENST00000373023; = p.K676E on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 298/299 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INSR | c.1877T>G p.L626R | Missense Mutation (SNP) | VAF 97/145 reads (67%) | SIFT tolerated (0.95); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ITGB4 | c.3806C>T p.P1269L | Missense Mutation (SNP) | VAF 207/342 reads (61%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- JPH2 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 578/794 reads (73%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); called by muse, mutect2
- KIF4B | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 98/301 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHDC4 | c.1316T>G p.V439G | Missense Mutation (SNP) | VAF 548/548 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- KLHL30 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 106/240 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- KLRG2 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 261/708 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- KMT2D | c.6806C>T p.S2269F | Missense Mutation (SNP) | VAF 436/561 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- KRT10 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 95/226 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LAMA5 | c.2735T>C p.V912A | Missense Mutation (SNP) | VAF 355/473 reads (75%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LPL | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 38/184 reads (21%) | called by muse, mutect2
- LRPPRC | c.239C>A p.S80Y | Missense Mutation (SNP) | VAF 217/394 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- LTBP3 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 249/522 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- LTBP3 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 249/526 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- MAGEB3 | c.848C>A p.T283N | Missense Mutation (SNP) | VAF 314/314 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP3K13 | c.1120G>A p.V374I | Missense Mutation (SNP) | VAF 65/271 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- MAP9 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 220/354 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- MIEF1 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 157/349 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MIOX | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 188/370 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MLH3 | c.4018del p.Q1340Rfs*12 (on ENST00000355774 / NM_001040108.2; = p.Q1316Rfs*12 on NM_014381.3) | Frame Shift Del (DEL) | VAF 303/488 reads (62%) | called by mutect2, pindel, varscan2
- MLPH | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 68/136 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MOBP | c.331C>T p.P111S (on ENST00000420739; = p.P135S on NM_001278322.2) | Missense Mutation (SNP) | VAF 252/696 reads (36%) | PolyPhen possibly damaging (0.803); called by muse, varscan2
- MOBP | c.332C>T p.P111L (on ENST00000420739; = p.P135L on NM_001278322.2) | Missense Mutation (SNP) | VAF 275/732 reads (38%) | PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- MRGPRE | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 302/444 reads (68%) | SIFT tolerated (0.38); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MUC16 | c.25952G>A p.G8651E | Missense Mutation (SNP) | VAF 102/382 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MUC5B | c.16926G>A p.G5642= | Splice Region (SNP) | VAF 101/333 reads (30%) | called by muse, mutect2, varscan2
- MYO16 | c.4721C>T p.P1574L | Missense Mutation (SNP) | VAF 178/254 reads (70%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NCKAP5L | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 81/441 reads (18%) | called by muse, mutect2, varscan2
- NCOR2 | c.3199C>T p.P1067S | Missense Mutation (SNP) | VAF 483/626 reads (77%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NDST3 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 105/306 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NEO1 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 210/274 reads (77%) | called by muse, mutect2, varscan2
- NGFR | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 277/702 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- NLRP1 | c.3356T>G p.M1119R | Missense Mutation (SNP) | VAF 243/558 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NLRP2 | c.2935A>C p.S979R | Missense Mutation (SNP) | VAF 105/369 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOL8 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 608/608 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NPIPB15 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 45/495 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NR1D2 | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 222/375 reads (59%) | SIFT tolerated (0.39); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- NUDT14 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 132/462 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NUDT9 | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 112/112 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OR2J3 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 272/279 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- OR5W2 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 134/248 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- OR6C6 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 275/275 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- OR6C75 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- OR8J2 | c.813C>A p.D271E | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, varscan2
- OTC | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 154/155 reads (99%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PANX1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 102/212 reads (48%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PAPLN | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 330/388 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PBRM1 | c.4009A>T p.I1337F | Missense Mutation (SNP) | VAF 294/489 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB1 | c.2074G>A p.V692I | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- PCDHGC5 | c.2011C>T p.P671S | Missense Mutation (SNP) | VAF 93/290 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.021); called by muse, varscan2
- PCYT2 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 146/392 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCYT2 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 146/387 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE3A | c.1592A>G p.Q531R | Missense Mutation (SNP) | VAF 129/129 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHF1 | c.688T>A p.Y230N | Missense Mutation (SNP) | VAF 365/377 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PKN1 | c.2335C>T p.P779S | Missense Mutation (SNP) | VAF 180/305 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLAGL2 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 190/542 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- PLEKHD1 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 358/438 reads (82%) | called by muse, mutect2, varscan2
- PLEKHG1 | c.2366G>A p.S789N | Missense Mutation (SNP) | VAF 258/286 reads (90%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PNPT1 | c.1796C>T p.S599F | Missense Mutation (SNP) | VAF 121/338 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- POU2F1 | c.873T>A p.F291L (on ENST00000541643 / NM_001365848.1; = p.F314L on NM_002697.4) | Missense Mutation (SNP) | VAF 194/421 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PRR14L | c.6142T>C p.Y2048H | Missense Mutation (SNP) | VAF 83/197 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRR5L | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 123/194 reads (63%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRSS12 | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 432/658 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- PSMD2 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 135/191 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTPRB | c.2824G>A p.A942T | Missense Mutation (SNP) | VAF 333/429 reads (78%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- PXMP2 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 213/213 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- RAC2 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 226/442 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- RANGRF | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 255/587 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASA3 | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 70/232 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RELN | c.9264T>G p.N3088K | Missense Mutation (SNP) | VAF 136/334 reads (41%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- REV3L | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 173/189 reads (92%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RRP1B | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- RSPH9 | c.730T>C p.W244R | Missense Mutation (SNP) | VAF 410/432 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.3260T>G p.I1087S | Missense Mutation (SNP) | VAF 135/288 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- SAMD7 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 221/277 reads (80%) | SIFT tolerated (0.25); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SATB2 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- SCN3A | c.2782G>A p.D928N | Missense Mutation (SNP) | VAF 354/477 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SEC16A | c.3274C>T p.Q1092* | Nonsense Mutation (SNP) | VAF 58/650 reads (9%) | called by muse, mutect2
- SEC24C | c.1383T>G p.F461L | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SEPTIN6 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 211/211 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- SHROOM2 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 405/405 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- SIMC1 | c.1045G>A p.G349R (on ENST00000443967 / NM_001308196.1; = p.G368R on NM_001308195.2) | Missense Mutation (SNP) | VAF 135/260 reads (52%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIRT7 | c.547del p.I183Sfs*28 | Frame Shift Del (DEL) | VAF 201/388 reads (52%) | called by mutect2, pindel*, varscan2
- SLC16A12 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 56/262 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- SLC23A3 | c.1016G>A p.G339D | Missense Mutation (SNP) | VAF 113/253 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- SLC24A1 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 83/409 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SLC5A5 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 111/191 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- SLC9A3R1 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 59/439 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- SLCO4A1 | c.522_525dup p.G176Lfs*24 | Frame Shift Ins (INS) | VAF 226/746 reads (30%) | called by mutect2, pindel, varscan2
- SLITRK3 | c.1757T>C p.V586A | Missense Mutation (SNP) | VAF 169/218 reads (78%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); called by muse, varscan2
- SLX4 | c.4022G>A p.R1341K | Missense Mutation (SNP) | VAF 108/567 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SMARCAL1 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- SNX8 | c.704T>A p.L235H | Missense Mutation (SNP) | VAF 78/487 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SOX1 | c.328C>G p.L110V | Missense Mutation (SNP) | VAF 122/365 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- SPAG1 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 134/317 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- SPATA31D1 | c.4718C>T p.P1573L | Missense Mutation (SNP) | VAF 172/172 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- SPEG | c.8366C>T p.S2789L | Missense Mutation (SNP) | VAF 100/268 reads (37%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- SPHKAP | c.4753G>A p.G1585R (on ENST00000392056 / NM_001142644.2; = p.G1556R on NM_030623.3) | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- SPINK5 | c.1786C>T p.H596Y | Missense Mutation (SNP) | VAF 57/219 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- SRCIN1 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 188/348 reads (54%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- SRRM3 | c.1913C>T p.P638L | Missense Mutation (SNP) | VAF 199/553 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SSTR1 | c.176T>C p.I59T | Missense Mutation (SNP) | VAF 119/332 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- SSU72P3 | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 65/278 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- STK32B | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 381/476 reads (80%) | SIFT tolerated (0.21); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- STRADA | c.1022C>T p.S341F (on ENST00000336174 / NM_001363786.1; = p.S304F on NM_153335.6) | Missense Mutation (SNP) | VAF 340/487 reads (70%) | SIFT tolerated (0.09); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SUB1 | c.151T>G p.S51A | Missense Mutation (SNP) | VAF 39/315 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SULT6B1 | c.644A>C p.K215T (on ENST00000535679 / NM_001367551.1; = p.K177T on NM_001032377.2) | Missense Mutation (SNP) | VAF 148/363 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SUSD3 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 569/570 reads (100%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- SVIL | c.94C>G p.H32D | Missense Mutation (SNP) | VAF 300/570 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SYNGR1 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 377/779 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- SZT2 | c.5287C>T p.L1763F (on ENST00000634258 / NM_001365999.1; = p.L1706F on NM_015284.4) | Missense Mutation (SNP) | VAF 285/287 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- TAF3 | c.1631G>A p.R544K | Missense Mutation (SNP) | VAF 135/314 reads (43%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TBC1D30 | c.772-1G>A p.X258_splice (on ENST00000542120; = p.X95_splice on NM_015279.2 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 121/161 reads (75%) | called by muse, mutect2, varscan2
- THBS1 | c.31T>C p.F11L | Missense Mutation (SNP) | VAF 64/379 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- THBS1 | c.998T>C p.V333A | Missense Mutation (SNP) | VAF 62/359 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- TIAM2 | c.4727G>A p.G1576E (on ENST00000529824; = p.G1547E on NM_012454.3) | Missense Mutation (SNP) | VAF 257/275 reads (93%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TIMM21 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 65/83 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- TMEM18 | c.170T>A p.L57Q | Missense Mutation (SNP) | VAF 127/301 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TMEM240 | c.318G>A p.W106* | Nonsense Mutation (SNP) | VAF 690/691 reads (100%) | called by muse, mutect2, varscan2
- TMEM71 | c.482G>A p.G161E (on ENST00000523829 / NM_001382398.1; = p.G142E on NM_144649.3) | Missense Mutation (SNP) | VAF 111/180 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMPRSS15 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 76/274 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TOM1 | c.485T>G p.I162S | Missense Mutation (SNP) | VAF 231/463 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- TP53 | c.467_470delinsTTG p.R156Lfs*14 | Frame Shift Del (DEL) | VAF 224/726 reads (31%) | called by pindel, varscan2*
- TPH1 | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- TPTE2 | c.634T>C p.Y212H (on ENST00000400230 / NM_199254.2; = p.Y135H on NM_130785.3) | Missense Mutation (SNP) | VAF 90/153 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRABD2A | c.223A>C p.K75Q | Missense Mutation (SNP) | VAF 305/542 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRAJ19 | c.18C>A p.Y6* | Nonsense Mutation (SNP) | VAF 123/208 reads (59%) | called by muse, mutect2, varscan2
- TRIB2 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 340/587 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIB2 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 340/584 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM58 | c.423A>G p.V141= | Splice Region (SNP) | VAF 120/242 reads (50%) | called by muse, mutect2, varscan2
- TRIP12 | c.4199C>T p.P1400L | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TTC17 | c.3151G>A p.D1051N | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TTC9C | c.358C>T p.H120Y | Missense Mutation (SNP) | VAF 148/306 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- TTLL6 | c.827G>T p.C276F | Missense Mutation (SNP) | VAF 76/412 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.61028G>A p.G20343E (on ENST00000591111; = p.G12919E on NM_003319.4) | Missense Mutation (SNP) | VAF 425/513 reads (83%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TUB | c.73C>T p.Q25* (on ENST00000299506 / NM_177972.3; = p.Q80* on NM_003320.4) | Nonsense Mutation (SNP) | VAF 75/206 reads (36%) | called by muse, mutect2, varscan2
- TYW1 | c.1229C>T p.T410I | Missense Mutation (SNP) | VAF 182/434 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- UNC5D | c.2561C>T p.P854L | Missense Mutation (SNP) | VAF 278/358 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- URGCP | c.976G>A p.D326N (on ENST00000453200 / NM_001077663.3; = p.D317N on NM_017920.4) | Missense Mutation (SNP) | VAF 317/484 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- USP40 | c.1518G>A p.M506I | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- USP9Y | c.3585A>T p.Q1195H | Missense Mutation (SNP) | VAF 162/162 reads (100%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- VCX3B | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 222/448 reads (50%) | called by muse, varscan2
- WDR6 | c.2272C>T p.P758S | Missense Mutation (SNP) | VAF 197/547 reads (36%) | SIFT tolerated (0.98); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- WDR87 | c.6924G>C p.E2308D | Missense Mutation (SNP) | VAF 112/527 reads (21%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- WDR90 | c.3780G>A p.W1260* | Nonsense Mutation (SNP) | VAF 488/614 reads (79%) | called by muse, mutect2, varscan2
- WIPI2 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 46/369 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNK2 | c.4519G>T p.A1507S (on ENST00000297954 / NM_001282394.1; = p.A1470S on NM_006648.3) | Missense Mutation (SNP) | VAF 196/1024 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- WT1 | c.892A>T p.N298Y | Missense Mutation (SNP) | VAF 1368/1458 reads (94%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- XKR4 | c.1420C>T p.L474F | Missense Mutation (SNP) | VAF 146/336 reads (43%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZDBF2 | c.6478C>T p.P2160S | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZFP36L2 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 407/954 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- ZNF107 | c.1552C>T p.H518Y | Missense Mutation (SNP) | VAF 178/306 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ZNF214 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 82/158 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF229 | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 86/234 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.178); called by muse, varscan2
- ZNF282 | c.1312A>T p.N438Y | Missense Mutation (SNP) | VAF 246/664 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF407 | c.6418G>C p.G2140R | Missense Mutation (SNP) | VAF 133/587 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- ZNF438 | c.692A>T p.Q231L | Missense Mutation (SNP) | VAF 251/493 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF555 | c.1162A>G p.R388G | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- ZNF628 | c.2830G>A p.G944S | Missense Mutation (SNP) | VAF 259/410 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ZNF710 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 123/734 reads (17%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF804A | c.1784G>A p.R595K | Missense Mutation (SNP) | VAF 226/276 reads (82%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2
- ZNF862 | c.137-1G>A p.X46_splice | Splice Site (SNP) | VAF 134/239 reads (56%) | called by muse, mutect2, varscan2
- ZSWIM5 | c.1335G>A p.W445* | Nonsense Mutation (SNP) | VAF 370/370 reads (100%) | called by muse, mutect2, varscan2
- ZSWIM8 | c.4391G>A p.G1464E (on ENST00000605216 / NM_001242487.2; = p.G1469E on NM_015037.3) | Missense Mutation (SNP) | VAF 300/439 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZZEF1 | c.6038A>G p.E2013G | Missense Mutation (SNP) | VAF 200/433 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABHD11 | c.894C>T p.I298= | Silent (SNP) | VAF 256/446 reads (57%) | called by muse, mutect2, varscan2
- ABLIM3 | c.1503G>A p.R501= | Silent (SNP) | VAF 66/208 reads (32%) | called by muse, mutect2, varscan2
- ACKR1 | c.345C>G p.V115= | Silent (SNP) | VAF 270/615 reads (44%) | called by muse, mutect2, varscan2
- ADAM29 | c.2028C>T p.F676= | Silent (SNP) | VAF 97/311 reads (31%) | called by muse, mutect2, varscan2
- ADAMTS19 | c.3537C>T p.C1179= | Silent (SNP) | VAF 74/126 reads (59%) | catalogued as rs753897249; called by muse, mutect2, varscan2
- ADAMTS3 | c.3247C>T p.L1083= | Silent (SNP) | VAF 190/193 reads (98%) | catalogued as COSV54402930; called by muse, mutect2, varscan2
- ADAR | c.489G>A p.G163= | Silent (SNP) | VAF 234/469 reads (50%) | called by mutect2, varscan2
- ADGRV1 | c.2428C>T p.L810= | Silent (SNP) | VAF 49/179 reads (27%) | called by muse, mutect2, varscan2
- ADH1C | c.501G>A p.L167= | Silent (SNP) | VAF 147/385 reads (38%) | called by muse, mutect2, varscan2
- AFG3L2 | c.2185C>T p.L729= | Silent (SNP) | VAF 107/149 reads (72%) | catalogued as rs752028185; called by muse, mutect2, varscan2
- AHNAK | c.14238G>A p.V4746= | Silent (SNP) | VAF 186/388 reads (48%) | called by muse, mutect2, varscan2
- AKAP9 | c.9795A>G p.E3265= (on ENST00000359028; = p.E3241= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 75/200 reads (38%) | catalogued as COSV62349674; called by muse, mutect2, varscan2
- ALK | c.3583C>T p.L1195= | Silent (SNP) | VAF 180/440 reads (41%) | called by muse, mutect2, varscan2
- AMT | c.48G>A p.Q16= | Silent (SNP) | VAF 154/418 reads (37%) | called by muse, mutect2, varscan2
- ANGPT1 | c.303G>A p.E101= | Silent (SNP) | VAF 56/271 reads (21%) | called by muse, varscan2
- ANGPTL1 | c.420G>A p.E140= | Silent (SNP) | VAF 167/357 reads (47%) | called by muse, mutect2, varscan2
- ANKRD12 | c.5193C>T p.I1731= | Silent (SNP) | VAF 159/202 reads (79%) | catalogued as COSV100041375; called by muse, mutect2, varscan2
- ANKRD35 | c.2280C>T p.S760= | Silent (SNP) | VAF 274/600 reads (46%) | called by muse, mutect2, varscan2
- ARPP21 | c.1080G>A p.R360= | Silent (SNP) | VAF 145/373 reads (39%) | catalogued as COSV104386479; called by muse, mutect2, varscan2
- ASAH2 | c.1683G>A p.G561= | Silent (SNP) | VAF 145/267 reads (54%) | called by muse, mutect2, varscan2
- ASCC2 | c.1068C>T p.S356= | Silent (SNP) | VAF 266/468 reads (57%) | called by muse, mutect2, varscan2
- ASTN2 | c.612C>T p.I204= | Silent (SNP) | VAF 255/255 reads (100%) | called by muse, mutect2, varscan2
- ATP1A4 | c.2424G>A p.L808= | Silent (SNP) | VAF 188/379 reads (50%) | called by muse, mutect2, varscan2
- ATP1B3 | c.333G>A p.K111= | Silent (SNP) | VAF 158/189 reads (84%) | called by muse, mutect2
- ATP2A1 | c.873G>A p.G291= | Silent (SNP) | VAF 240/319 reads (75%) | called by muse, varscan2
- ATP2B4 | c.579C>T p.I193= | Silent (SNP) | VAF 195/465 reads (42%) | called by muse, mutect2, varscan2
- B3GNTL1 | c.447C>T p.S149= | Silent (SNP) | VAF 366/636 reads (58%) | called by muse, mutect2, varscan2
- BBS4 | c.1554G>A p.E518= | Silent (SNP) | VAF 142/166 reads (86%) | catalogued as rs752394112; called by muse, mutect2, varscan2
- BFAR | c.1191C>T p.F397= | Silent (SNP) | VAF 108/507 reads (21%) | called by muse, mutect2, varscan2
- BIRC6 | c.11146C>T p.L3716= | Silent (SNP) | VAF 241/551 reads (44%) | called by muse, mutect2, varscan2
- BMP1 | c.324C>T p.A108= | Silent (SNP) | VAF 80/412 reads (19%) | catalogued as COSV59244083; called by muse, mutect2, varscan2
- BTNL9 | c.684C>T p.S228= | Silent (SNP) | VAF 58/214 reads (27%) | called by muse, mutect2, varscan2
- C15orf39 | c.2724T>A p.I908= | Silent (SNP) | VAF 74/499 reads (15%) | called by muse, mutect2, varscan2
- C8orf34 | c.387C>T p.D129= | Silent (SNP) | VAF 182/242 reads (75%) | catalogued as rs1379014178; called by muse, varscan2
- C8orf48 | c.519G>A p.L173= | Silent (SNP) | VAF 231/303 reads (76%) | catalogued as rs945374415; called by muse, mutect2, varscan2
- CC2D2B | c.951A>G p.Q317= | Silent (SNP) | VAF 190/243 reads (78%) | called by muse, mutect2, varscan2
- CCDC141 | c.3552C>T p.S1184= | Silent (SNP) | VAF 405/476 reads (85%) | catalogued as rs1278132487; called by muse, mutect2, varscan2
- CCDC141 | c.2982G>A p.V994= | Silent (SNP) | VAF 327/406 reads (81%) | catalogued as COSV55369892; called by muse, mutect2, varscan2
- CCDC182 | c.360G>A p.P120= | Silent (SNP) | VAF 165/499 reads (33%) | catalogued as rs781563994; called by muse, mutect2, varscan2
- CCDC62 | c.967C>T p.L323= | Silent (SNP) | VAF 52/232 reads (22%) | called by muse, mutect2, varscan2
- CCR2 | c.801C>T p.T267= | Silent (SNP) | VAF 98/341 reads (29%) | called by muse, mutect2, varscan2
- CD84 | c.192A>G p.T64= | Silent (SNP) | VAF 219/446 reads (49%) | called by muse, mutect2, varscan2
- CHPF2 | c.876G>A p.E292= | Silent (SNP) | VAF 239/389 reads (61%) | called by muse, mutect2, varscan2
- CHPT1 | c.243C>T p.L81= | Silent (SNP) | VAF 388/467 reads (83%) | called by muse, mutect2, varscan2
- CIC | c.147G>A p.Q49= | Silent (SNP) | VAF 287/438 reads (66%) | called by muse, mutect2, varscan2
- CIC | c.4344C>T p.D1448= | Silent (SNP) | VAF 72/231 reads (31%) | catalogued as rs377587490, COSV99031257; called by muse, mutect2, varscan2
- CLUAP1 | c.933C>T p.N311= | Silent (SNP) | VAF 29/177 reads (16%) | catalogued as rs750353977, COSV58895516; called by muse, mutect2, varscan2
- CNTN2 | c.1506C>T p.I502= | Silent (SNP) | VAF 154/301 reads (51%) | catalogued as rs1186028093, COSV100085411; called by muse, mutect2, varscan2
- CNTN2 | c.1740C>T p.R580= | Silent (SNP) | VAF 189/388 reads (49%) | catalogued as rs199872560; called by muse, mutect2, varscan2
- COL15A1 | c.3363C>T p.G1121= | Silent (SNP) | VAF 491/492 reads (100%) | catalogued as COSV66643357; called by muse, varscan2
- CPA3 | c.297G>A p.E99= | Silent (SNP) | VAF 93/138 reads (67%) | catalogued as rs1157828534; called by muse, mutect2, varscan2
- DAO | c.579C>T p.P193= | Silent (SNP) | VAF 64/340 reads (19%) | catalogued as COSV57321483; called by muse, mutect2, varscan2
- DDX42 | c.1794C>T p.A598= | Silent (SNP) | VAF 293/449 reads (65%) | catalogued as rs142758870, COSV63789533; called by muse, mutect2, varscan2
- DENND1B | c.2037C>T p.D679= | Silent (SNP) | VAF 81/436 reads (19%) | called by muse, mutect2, varscan2
- DENND1B | c.1482G>A p.K494= | Silent (SNP) | VAF 123/265 reads (46%) | called by muse, mutect2, varscan2
- DHX35 | c.1707C>T p.F569= | Silent (SNP) | VAF 201/307 reads (65%) | catalogued as COSV52668201, COSV52671914; called by muse, mutect2, varscan2
- DMD | c.4164C>T p.F1388= | Silent (SNP) | VAF 246/246 reads (100%) | catalogued as COSV63744786; called by muse, mutect2, varscan2
- DMKN | c.915C>T p.S305= | Silent (SNP) | VAF 487/605 reads (80%) | catalogued as COSV100303455; called by muse, mutect2, varscan2
- DMP1 | c.903C>T p.S301= | Silent (SNP) | VAF 157/157 reads (100%) | called by muse, mutect2, varscan2
- DNAH11 | c.9063C>T p.S3021= | Silent (SNP) | VAF 153/232 reads (66%) | catalogued as rs368820581; called by muse, mutect2, varscan2
- DNMT3B | c.1479G>T p.T493= | Silent (SNP) | VAF 264/409 reads (65%) | called by muse, mutect2, varscan2
- DUSP8 | c.1443G>A p.R481= | Silent (SNP) | VAF 88/277 reads (32%) | catalogued as rs1334982484; called by muse, mutect2, varscan2
- DYNC1H1 | c.8469G>A p.R2823= | Silent (SNP) | VAF 152/494 reads (31%) | called by muse, mutect2, varscan2
- DYNC2I1 | c.402C>T p.L134= | Silent (SNP) | VAF 352/588 reads (60%) | called by muse, mutect2, varscan2
- EFCAB14 | c.1287C>T p.S429= | Silent (SNP) | VAF 240/240 reads (100%) | called by muse, mutect2, varscan2
- EFCAB8 | c.2238G>A p.P746= | Silent (SNP) | VAF 153/454 reads (34%) | catalogued as rs746382926; called by muse, mutect2, varscan2
- EIPR1 | c.786C>T p.T262= | Silent (SNP) | VAF 234/444 reads (53%) | catalogued as rs779480832; called by muse, mutect2, varscan2
- ENTR1 | c.189C>G p.P63= | Silent (SNP) | VAF 59/561 reads (11%) | called by muse, mutect2, varscan2
- ERI2 | c.216G>A p.Q72= | Silent (SNP) | VAF 66/377 reads (18%) | called by muse, mutect2, varscan2
- ESR2 | c.1218C>G p.L406= | Silent (SNP) | VAF 53/328 reads (16%) | called by muse, mutect2, varscan2
- EXOC4 | c.258C>T p.S86= | Silent (SNP) | VAF 167/313 reads (53%) | called by muse, mutect2, varscan2
- F13A1 | c.468G>A p.G156= | Silent (SNP) | VAF 312/326 reads (96%) | called by muse, mutect2, varscan2
- FAM205A | c.2196G>A p.L732= | Silent (SNP) | VAF 81/423 reads (19%) | catalogued as rs1755267; called by muse, mutect2, varscan2
- FAT3 | c.12210G>A p.R4070= | Silent (SNP) | VAF 128/277 reads (46%) | catalogued as COSV53189407; called by muse, mutect2, varscan2
- FER1L6 | c.1113C>T p.P371= | Silent (SNP) | VAF 240/435 reads (55%) | called by muse, mutect2, varscan2
- FGF1 | c.201G>A p.G67= | Silent (SNP) | VAF 124/196 reads (63%) | catalogued as rs1165372402; called by muse, mutect2, varscan2
- FIGNL1 | c.1665C>T p.A555= | Silent (SNP) | VAF 236/375 reads (63%) | called by muse, mutect2, varscan2
- FSIP2 | c.5202G>A p.A1734= | Silent (SNP) | VAF 37/355 reads (10%) | catalogued as rs568599074, COSV58084044; called by muse, mutect2, varscan2
- FSIP2 | c.14646A>G p.K4882= | Silent (SNP) | VAF 37/390 reads (9%) | called by muse, mutect2
- GABRB1 | c.294T>A p.S98= | Silent (SNP) | VAF 40/311 reads (13%) | called by muse, varscan2
- GAMT | c.423G>A p.E141= | Silent (SNP) | VAF 129/218 reads (59%) | called by muse, mutect2, varscan2
- GAPVD1 | c.1569C>T p.P523= | Silent (SNP) | VAF 298/300 reads (99%) | called by muse, mutect2, varscan2
- GART | c.2079C>T p.V693= | Silent (SNP) | VAF 54/111 reads (49%) | called by muse, mutect2, varscan2
- GBA3 | c.423C>T p.S141= | Silent (SNP) | VAF 72/369 reads (20%) | catalogued as COSV101545524, COSV72437850; called by muse, mutect2, varscan2
- GLCE | c.255C>T p.P85= | Silent (SNP) | VAF 72/456 reads (16%) | catalogued as rs371241193; called by muse, mutect2, varscan2
- GMIP | c.1671C>T p.P557= | Silent (SNP) | VAF 120/225 reads (53%) | called by muse, mutect2, varscan2
- GOLGA6L7 | c.516G>A p.R172= | Silent (SNP) | VAF 133/159 reads (84%) | called by muse, mutect2, varscan2
- GPD1L | c.690C>T p.I230= | Silent (SNP) | VAF 284/487 reads (58%) | called by muse, mutect2, varscan2
- GPR65 | c.372C>T p.F124= | Silent (SNP) | VAF 69/382 reads (18%) | catalogued as rs755830314, COSV50864553; called by muse, mutect2, varscan2
- GRID1 | c.1668C>T p.S556= | Silent (SNP) | VAF 75/250 reads (30%) | catalogued as rs146184813; called by muse, mutect2, varscan2
- GRIK2 | c.1458G>A p.G486= | Silent (SNP) | VAF 20/264 reads (8%) | catalogued as rs867832831, COSV59715366; called by muse, mutect2
- HABP2 | c.666C>T p.L222= | Silent (SNP) | VAF 274/351 reads (78%) | catalogued as COSV63637700; called by muse, mutect2, varscan2
- HEATR6 | c.2512C>T p.L838= | Silent (SNP) | VAF 187/306 reads (61%) | catalogued as COSV99482457; called by muse, mutect2, varscan2
- HFM1 | c.2793C>T p.S931= | Silent (SNP) | VAF 156/156 reads (100%) | called by muse, mutect2, varscan2
- HHIP | c.966G>T p.V322= | Silent (SNP) | VAF 36/220 reads (16%) | catalogued as rs1353654008; called by muse, varscan2
- HTR1B | c.813C>T p.N271= | Silent (SNP) | VAF 190/203 reads (94%) | called by muse, mutect2, varscan2
- IBA57 | c.297C>T p.F99= | Silent (SNP) | VAF 417/750 reads (56%) | catalogued as COSV64510799; called by muse, mutect2, varscan2
- IGLV1-44 | c.12C>T p.F4= | Silent (SNP) | VAF 136/294 reads (46%) | catalogued as rs772791590; called by muse, mutect2, varscan2
- IL1RL1 | c.210A>G p.Q70= | Silent (SNP) | VAF 62/291 reads (21%) | catalogued as rs770243947; called by muse, mutect2, varscan2
- IPCEF1 | c.1026C>T p.S342= | Silent (SNP) | VAF 234/253 reads (92%) | called by muse, mutect2, varscan2
- ITGB4 | c.3807C>T p.P1269= | Silent (SNP) | VAF 209/351 reads (60%) | catalogued as CD056463; called by muse, mutect2, varscan2
- ITGB7 | c.420C>T p.L140= | Silent (SNP) | VAF 81/415 reads (20%) | called by muse, mutect2, varscan2
- KALRN | c.1701G>A p.G567= | Silent (SNP) | VAF 194/256 reads (76%) | catalogued as COSV53763793; called by muse, mutect2, varscan2
- KATNAL2 | c.1248G>A p.K416= (on ENST00000356157 / NM_001353899.1; = p.K344= on NM_031303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 274/345 reads (79%) | called by muse, mutect2, varscan2
- KAZN | c.1872C>T p.I624= | Silent (SNP) | VAF 302/303 reads (100%) | catalogued as rs1347753244; called by muse, mutect2, varscan2
- KCNC3 | c.1020G>A p.V340= | Silent (SNP) | VAF 106/364 reads (29%) | called by muse, mutect2, varscan2
- KCNK5 | c.678C>T p.F226= | Silent (SNP) | VAF 215/225 reads (96%) | catalogued as rs1017757180, COSV100851769; called by muse, mutect2, varscan2
- KIF19 | c.2301C>T p.S767= | Silent (SNP) | VAF 136/409 reads (33%) | called by muse, mutect2, varscan2
- KIF4B | c.3636G>A p.K1212= | Silent (SNP) | VAF 145/221 reads (66%) | called by muse, mutect2, varscan2
- KIR2DL3 | c.360C>T p.I120= | Silent (SNP) | VAF 44/211 reads (21%) | catalogued as rs771556841, COSV60897767; called by muse, mutect2, varscan2
- KLF18 | c.1143C>T p.S381= | Silent (SNP) | VAF 355/430 reads (83%) | called by muse, varscan2
- KLHL30 | c.1059G>A p.K353= | Silent (SNP) | VAF 104/238 reads (44%) | called by muse, mutect2, varscan2
- KLRG2 | c.333G>A p.G111= | Silent (SNP) | VAF 263/715 reads (37%) | called by muse, mutect2, varscan2
- LENG8 | c.1632C>T p.D544= | Silent (SNP) | VAF 324/503 reads (64%) | catalogued as rs1376344878; called by muse, mutect2, varscan2
- LINC02218 | c.459G>A p.V153= | Silent (SNP) | VAF 119/391 reads (30%) | called by muse, varscan2
- LMOD1 | c.480G>A p.K160= | Silent (SNP) | VAF 300/639 reads (47%) | catalogued as COSV100939298; called by muse, mutect2, varscan2
- LRP1 | c.7728G>A p.G2576= | Silent (SNP) | VAF 676/743 reads (91%) | catalogued as COSV54510779; called by muse, mutect2, varscan2
- LRRC37A | c.4188C>T p.A1396= | Silent (SNP) | VAF 117/471 reads (25%) | catalogued as COSV100208110; called by muse, mutect2
- LRRC37A2 | c.4188C>T p.A1396= | Silent (SNP) | VAF 86/546 reads (16%) | called by muse, mutect2, varscan2
- LRRC37A3 | c.1116G>A p.E372= | Silent (SNP) | VAF 259/1680 reads (15%) | catalogued as rs1433969301; called by muse, mutect2, varscan2
- LRRIQ1 | c.3708C>T p.A1236= | Silent (SNP) | VAF 53/318 reads (17%) | catalogued as COSV101279407, COSV67833467; called by muse, mutect2, varscan2
- MACC1 | c.819G>A p.L273= | Silent (SNP) | VAF 79/258 reads (31%) | called by muse, mutect2, varscan2
- MAGEL2 | c.1416C>T p.I472= | Silent (SNP) | VAF 670/1026 reads (65%) | called by muse, mutect2, varscan2
- MAN2C1 | c.1875C>T p.L625= | Silent (SNP) | VAF 100/628 reads (16%) | catalogued as rs576306046; called by muse, mutect2, varscan2
- MAPK7 | c.1953C>T p.V651= | Silent (SNP) | VAF 464/1142 reads (41%) | catalogued as COSV55190153; called by muse, mutect2, varscan2
- MAPK9 | c.174C>T p.S58= | Silent (SNP) | VAF 67/224 reads (30%) | called by muse, mutect2, varscan2
- MCCC1 | c.1395C>T p.T465= | Silent (SNP) | VAF 123/175 reads (70%) | called by muse, mutect2, varscan2
- MCM10 | c.1842C>T p.F614= (on ENST00000484800 / NM_182751.3; = p.F613= on NM_018518.5) | Silent (SNP) | VAF 206/426 reads (48%) | catalogued as rs1317676596, COSV66336771; called by muse, mutect2, varscan2
- MED16 | c.210C>T p.P70= | Silent (SNP) | VAF 140/240 reads (58%) | catalogued as rs139294457; called by muse, mutect2, varscan2
- MED9 | c.15G>A p.G5= | Silent (SNP) | VAF 345/623 reads (55%) | catalogued as rs778963066; called by muse, mutect2, varscan2
- MFAP3L | c.627C>T p.P209= | Silent (SNP) | VAF 117/388 reads (30%) | called by muse, mutect2, varscan2
- MGAM | c.2940C>A p.A980= | Silent (SNP) | VAF 173/338 reads (51%) | called by muse, mutect2, varscan2
- MIEF1 | c.168C>T p.A56= | Silent (SNP) | VAF 155/343 reads (45%) | catalogued as rs745489780; called by muse, mutect2, varscan2
- MSR1 | c.195C>T p.I65= | Silent (SNP) | VAF 195/267 reads (73%) | catalogued as rs768942318, COSV50528601; called by muse, mutect2, varscan2
- MST1R | c.3105C>T p.V1035= | Silent (SNP) | VAF 121/361 reads (34%) | called by muse, mutect2, varscan2
- MYLK2 | c.114C>T p.P38= | Silent (SNP) | VAF 186/633 reads (29%) | catalogued as rs772195303; called by muse, mutect2, varscan2
- MYRF | c.471C>T p.L157= (on ENST00000278836 / NM_001127392.3; = p.L148= on NM_013279.4) | Silent (SNP) | VAF 145/320 reads (45%) | called by muse, mutect2, varscan2
- NAALAD2 | c.1447C>T p.L483= | Silent (SNP) | VAF 85/187 reads (45%) | catalogued as COSV58965905; called by muse, mutect2, varscan2
- NAB2 | c.1008C>T p.L336= | Silent (SNP) | VAF 642/740 reads (87%) | called by muse, mutect2, varscan2
- NCAM2 | c.1512C>T p.I504= | Silent (SNP) | VAF 66/135 reads (49%) | catalogued as COSV53091066; called by muse, mutect2, varscan2
- NFATC2 | c.183C>T p.P61= | Silent (SNP) | VAF 462/650 reads (71%) | catalogued as rs760704113, COSV65358809; called by muse, mutect2, varscan2
- NLRP11 | c.312C>T p.F104= | Silent (SNP) | VAF 91/149 reads (61%) | catalogued as COSV64088401; called by muse, mutect2, varscan2
- NLRP3 | c.564C>T p.I188= | Silent (SNP) | VAF 231/478 reads (48%) | catalogued as rs147631017; called by muse, mutect2, varscan2
- NOC2L | c.852C>T p.F284= | Silent (SNP) | VAF 550/551 reads (100%) | catalogued as rs756485369, COSV58989740; called by muse, mutect2, varscan2
- NOS1 | c.1068A>G p.K356= | Silent (SNP) | VAF 333/409 reads (81%) | called by muse, mutect2, varscan2
- NOTCH2 | c.6057G>A p.R2019= | Silent (SNP) | VAF 218/218 reads (100%) | called by muse, mutect2, varscan2
- NPAS1 | c.1602G>A p.R534= | Silent (SNP) | VAF 384/564 reads (68%) | catalogued as rs747248302; called by muse, mutect2, varscan2
- NPC1L1 | c.2010C>T p.L670= | Silent (SNP) | VAF 125/421 reads (30%) | catalogued as rs770902496; called by muse, mutect2, varscan2
- NPLOC4 | c.1239G>A p.K413= | Silent (SNP) | VAF 287/501 reads (57%) | catalogued as rs1397615642; called by muse, mutect2, varscan2
- NTRK2 | c.843C>T p.L281= | Silent (SNP) | VAF 324/326 reads (99%) | called by muse, mutect2, varscan2
- OR10A7 | c.267G>A p.R89= | Silent (SNP) | VAF 304/384 reads (79%) | catalogued as rs371021969; called by muse, varscan2
- OR10C1 | c.417C>T p.H139= (on ENST00000622521; = p.H137= on NM_013941.3) | Silent (SNP) | VAF 563/575 reads (98%) | catalogued as rs763072767, COSV65824022; called by muse, mutect2, varscan2
- OR13C2 | c.699G>A p.G233= | Silent (SNP) | VAF 160/269 reads (59%) | called by muse, mutect2, varscan2
- OR2G6 | c.837C>T p.T279= | Silent (SNP) | VAF 205/376 reads (55%) | catalogued as COSV100598035; called by muse, mutect2, varscan2
- OR2H2 | c.636C>T p.I212= | Silent (SNP) | VAF 415/435 reads (95%) | catalogued as rs752919216; called by muse, mutect2, varscan2
- OR2I1P | c.81C>T p.F27= | Silent (SNP) | VAF 349/354 reads (99%) | called by muse, mutect2, varscan2
- OR2T4 | c.906G>A p.K302= | Silent (SNP) | VAF 301/700 reads (43%) | called by muse, mutect2
- OR4Q2 | c.664C>T p.L222= | Silent (SNP) | VAF 111/167 reads (66%) | catalogued as rs1053804627; called by muse, mutect2, varscan2
- OR51T1 | c.435G>A p.V145= | Silent (SNP) | VAF 86/238 reads (36%) | catalogued as COSV59025838; called by muse, varscan2
- OR6B1 | c.252T>C p.S84= | Silent (SNP) | VAF 162/429 reads (38%) | catalogued as rs1244797216; called by muse, mutect2, varscan2
- OR6C76 | c.330C>T p.F110= | Silent (SNP) | VAF 218/271 reads (80%) | catalogued as COSV60389177; called by muse, mutect2, varscan2
- OR6N2 | c.802C>T p.L268= | Silent (SNP) | VAF 166/339 reads (49%) | catalogued as rs1234107958, COSV59412913, COSV59413345; called by muse, mutect2, varscan2
- OR8A1 | c.585G>A p.E195= | Silent (SNP) | VAF 111/227 reads (49%) | catalogued as rs1272594991, COSV99420571; called by muse, mutect2, varscan2
- OR9K2 | c.771G>A p.E257= (on ENST00000305377; = p.E235= on NM_001005243.1) | Silent (SNP) | VAF 239/296 reads (81%) | catalogued as rs1405711113, COSV59532570; called by muse, mutect2, varscan2
- OSBPL2 | c.1146C>T p.F382= (on ENST00000313733 / NM_144498.4; = p.F370= on NM_014835.4) | Silent (SNP) | VAF 127/423 reads (30%) | catalogued as rs759094013; called by muse, mutect2, varscan2
- OTOP3 | c.1350C>T p.I450= | Silent (SNP) | VAF 430/644 reads (67%) | catalogued as rs751996365, COSV100172777; called by muse, mutect2, varscan2
- P2RX3 | c.129C>T p.F43= | Silent (SNP) | VAF 98/220 reads (45%) | called by muse, mutect2, varscan2
- PANX3 | c.471C>T p.L157= | Silent (SNP) | VAF 166/362 reads (46%) | catalogued as rs992944475, COSV52513429; called by muse, mutect2, varscan2
- PAQR6 | c.309C>T p.T103= | Silent (SNP) | VAF 435/856 reads (51%) | catalogued as rs1211032793, COSV52745310; called by muse, mutect2, varscan2
- PAX1 | c.489G>A p.G163= | Silent (SNP) | VAF 134/371 reads (36%) | called by muse, mutect2, varscan2
- PCDHA10 | c.1389G>A p.V463= | Silent (SNP) | VAF 97/408 reads (24%) | catalogued as rs1554150030; called by muse, mutect2
- PCDHA3 | c.1284G>A p.R428= | Silent (SNP) | VAF 64/245 reads (26%) | catalogued as rs782571599, COSV63538565; called by muse, mutect2, varscan2
- PCDHB1 | c.2073G>A p.L691= | Silent (SNP) | VAF 54/191 reads (28%) | catalogued as COSV60632291; called by muse, mutect2, varscan2
- PCDHB8 | c.1545C>T p.F515= | Silent (SNP) | VAF 264/1170 reads (23%) | catalogued as rs782426664, COSV50787337; called by muse, varscan2
- PCDHB8 | c.1590C>T p.F530= | Silent (SNP) | VAF 144/1204 reads (12%) | catalogued as rs782668730; called by muse, varscan2
- PCDHGA12 | c.43C>T p.L15= | Silent (SNP) | VAF 108/170 reads (64%) | called by muse, mutect2, varscan2
- PCDHGB2 | c.1527G>C p.A509= | Silent (SNP) | VAF 134/378 reads (35%) | called by muse, mutect2, varscan2
- PCK1 | c.1327C>T p.L443= | Silent (SNP) | VAF 282/404 reads (70%) | called by muse, mutect2, varscan2
- PDCD1LG2 | c.162A>T p.A54= | Silent (SNP) | VAF 66/242 reads (27%) | called by muse, mutect2, varscan2
- PEG3 | c.603G>A p.A201= | Silent (SNP) | VAF 145/229 reads (63%) | catalogued as rs759512604, COSV55639049; called by muse, mutect2, varscan2
- PER1 | c.2394C>T p.F798= | Silent (SNP) | VAF 321/606 reads (53%) | catalogued as rs1448260985; called by muse, mutect2, varscan2
- PFKFB4 | c.642C>T p.S214= | Silent (SNP) | VAF 109/300 reads (36%) | catalogued as rs1318369424; called by muse, mutect2, varscan2
- PIEZO2 | c.3759C>A p.I1253= | Silent (SNP) | VAF 91/460 reads (20%) | called by muse, mutect2, varscan2
- PIP5K1B | c.1257C>T p.A419= | Silent (SNP) | VAF 197/197 reads (100%) | called by muse, mutect2, varscan2
- PITPNM3 | c.765C>T p.G255= | Silent (SNP) | VAF 161/380 reads (42%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.4575G>A p.E1525= | Silent (SNP) | VAF 104/241 reads (43%) | catalogued as COSV101005690; called by muse, mutect2, varscan2
- PLCE1 | c.3318C>T p.T1106= | Silent (SNP) | VAF 87/306 reads (28%) | called by muse, mutect2, varscan2
- PLEKHD1 | c.990C>T p.S330= | Silent (SNP) | VAF 354/436 reads (81%) | catalogued as COSV59447574; called by muse, mutect2, varscan2
- PLVAP | c.861C>T p.A287= | Silent (SNP) | VAF 263/414 reads (64%) | called by muse, mutect2, varscan2
- PNPLA1 | c.936G>A p.K312= (on ENST00000394571 / NM_001374623.1; = p.K217= on NM_173676.2) | Silent (SNP) | VAF 14/368 reads (4%) | catalogued as COSV57237672; called by muse, mutect2
- POU3F2 | c.930G>A p.R310= | Silent (SNP) | VAF 25/283 reads (9%) | called by muse, mutect2
- PPBP | c.138G>A p.A46= | Silent (SNP) | VAF 107/107 reads (100%) | catalogued as rs747703873, COSV56019765; called by muse, mutect2, varscan2
- PPFIBP2 | c.2385G>A p.E795= | Silent (SNP) | VAF 148/233 reads (64%) | catalogued as rs1381626338; called by muse, mutect2, varscan2
- PPP1R3A | c.3057G>A p.E1019= | Silent (SNP) | VAF 124/361 reads (34%) | catalogued as COSV52879434; called by muse, mutect2, varscan2
- PRAG1 | c.3579C>T p.S1193= | Silent (SNP) | VAF 295/398 reads (74%) | called by muse, mutect2, varscan2
- PRDM9 | c.1833G>A p.R611= | Silent (SNP) | VAF 221/728 reads (30%) | called by muse, mutect2, varscan2
- PRR23B | c.93G>A p.L31= | Silent (SNP) | VAF 367/490 reads (75%) | catalogued as rs781009963; called by muse, mutect2, varscan2
- PRSS55 | c.933G>A p.R311= | Silent (SNP) | VAF 286/373 reads (77%) | called by muse, mutect2, varscan2
- PSMD2 | c.447G>A p.E149= | Silent (SNP) | VAF 134/191 reads (70%) | called by muse, mutect2, varscan2
- PSTPIP1 | c.228C>T p.S76= | Silent (SNP) | VAF 94/523 reads (18%) | catalogued as COSV51200281; called by muse, mutect2, varscan2
- PTPRH | c.1848G>A p.A616= | Silent (SNP) | VAF 230/344 reads (67%) | catalogued as rs561329758, COSV54743004; called by muse, mutect2, varscan2
- PTX4 | c.621G>A p.Q207= (on ENST00000447419 / NM_001328608.2; = p.Q202= on NM_001013658.1) | Silent (SNP) | VAF 114/693 reads (16%) | called by muse, mutect2, varscan2
- PXMP2 | c.252G>A p.G84= | Silent (SNP) | VAF 214/214 reads (100%) | called by muse, mutect2, varscan2
- PYHIN1 | c.321G>A p.T107= | Silent (SNP) | VAF 167/340 reads (49%) | catalogued as COSV100932398; called by muse, mutect2, varscan2
- QRFPR | c.82C>T p.L28= | Silent (SNP) | VAF 358/611 reads (59%) | called by muse, mutect2, varscan2
- RAB44 | c.1365T>A p.I455= | Silent (SNP) | VAF 514/533 reads (96%) | called by muse, mutect2, varscan2
- REG3A | c.357T>C p.G119= | Silent (SNP) | VAF 103/276 reads (37%) | catalogued as rs1408546104; called by muse, mutect2, varscan2
- RIMS1 | c.3339G>A p.R1113= | Silent (SNP) | VAF 134/159 reads (84%) | catalogued as rs1222041993, COSV53444068; called by muse, mutect2, varscan2
- RPRD2 | c.270G>A p.R90= | Silent (SNP) | VAF 173/354 reads (49%) | called by muse, mutect2, varscan2
- RSPH14 | c.21C>T p.S7= | Silent (SNP) | VAF 152/296 reads (51%) | called by muse, mutect2, varscan2
125 further variants in this file (0 protein-altering or splice-affecting, 89 silent, 36 other) are not listed here.
